Surgical pathology report (de-identified scan), TCGA case TCGA-29-1688, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1688-01A (Primary Tumor).

[page 1 of 2]
Surg Path

TCGA-29-1688

CLINICAL HISTORY:
Ovarian carcinoma.

GROSS EXAMINATION:

A. "Right tube and ovary". In formalin. Received is an ovoid-shaped, tan hemorrhagic soft tissue measuring 9.5 x 6.5 x 2.5 cm. in greatest dimensions. There are multiple various-sized cystic structures on the serosa. The largest measures 1.5 x 1.5 x 1.0 cm. Part of the serosa is smooth and glistening. Multiple surgical clips are present. There is a small amount of attached soft tissue, probably the adnexa. The mucosal surface consists of multiple various-sized hemorrhagic cystic structures. Some of which are filled serous fluid and blood clots. Blocks are submitted as follows:

Blocks A1, A2 - Representative sections of the ovary.
Block A3 - Representative sections of the presumed adnexa.
Block A4 - More sections of the ovary.

B. "Left ovary". In formalin. Received is a pale-white ovoid soft tissue measuring 5.5 x 3.5 x 2.0 cm. in greatest dimensions. There are multiple various-sized cystic structures on the serosal surface and the largest one measures 0.4 x 0.4 x 0.3 cm. Otherwise, the surface is smooth and glistening. On cross-sections, the cysts are filled with serous fluid. Representative sections are submitted as Blocks B1 and B2.

C. "Peritoneal nodules. Fresh. Received is an aggregate of yellow, firm, fatty soft tissue measuring 12.5 x 8.5 x 3.0 cm. They consists of multiple various-sized indurated nodules measuring from 2.5 x 1.6 x 1.2 cm. to 0.4 x 0.3 x 0.2 cm. Representative sections of the specimen are submitted as Blocks C1 through C4.

D. "Tumor". In formalin. Received is a plaque-like, tan, hemorrhagic nodular structure which weighs 1810 grams and measures 35.0 x 27.0 x 5.5 cm. in greatest dimensions. On the surface, there are numerous small blood clots and tumor nodules in various sizes. The latter is fused in a conglomerate plaque structure. Serial sections reveal mostly solid tumor, mixed with blood clots and rather homogenous in nature. Representative sections are submitted as Blocks D1 through D7.

E. "Appendix". In formalin. Vermiform appendix and attached soft tissue measuring 6.0 x 3.0 x 0.7 cm. The attached soft tissue is yellow, hemorrhagic and nodular in nature. Cross-sections reveal a pale white infiltrates consistent with tumor. Representative sections are submitted as Blocks E1 and E2.

F. "Spleen". In formalin. Received is a bean-shaped, gray-pink spleen measuring 12.0 x 6.2 x 3.5 cm. It weighs 110 grams. The capsule is rather smooth and glistening over the superior surface; however, the ventral surface is centrally covered with fatty tissues and possibly intermixed with nodule structures. They are mostly situated in the hilum area. Serial sections reveal beefy-red surfaces; no infarcts or suspicious tumor infiltrates. Sections are submitted as follows:

Block F1 - Representative section of the spleen,
including the nodules.
Block F2 - More sections of the spleen, including the nodules and capsule.
Block F3 - Additional section of the spleen.

G. "Omentum". In formalin. Received is an aggregate of yellow, fatty soft

[page 2 of 2]
tissue measuring 17.0 x 9.5 x 3.5 cm. in greatest dimensions. The serosal surfaces are covered by numerous various-sized tumor nodules and some of them are arranged in a plaque-like fashion. Most of them are less than 0.8 cm. in greatest dimension. However, serial sections reveal nodules measure up to 2.0 x 1.0 x 0.8 cm. Representative sections are submitted as Blocks G1 through G5.

DIAGNOSIS:

TCGA-29-1688

A. "RIGHT TUBE AND OVARY":

INVASIVE MODERATELY DIFFERENTIATED SEROUS CYSTADENOCARCINOMA WITH VASCULAR CHANNEL INVASION. NO TUBAL TISSUE DETECTED.

B. "LEFT OVARY":

OVARIAN TISSUE WITH INVASIVE MODERATELY DIFFERENTIATED SEROUS CYSTADENOCARCINOMA.

C. "PERITONEAL NODULES":

OMENTAL TISSUE WITH MULTIPLE DEPOSITS OF SEROUS CYSTADENOCARCINOMA.

D. "TUMOR":

OMENTAL TISSUE WITH MULTIPLE DEPOSITS OF SEROUS CYSTADENOCARCINOMA.

E. "APPENDIX":

APPENDIX WITH FIBROUS LUMINAL OBLITERATION.

MESOAPPENDIX WITH DEPOSITS OF SEROUS CYSTADENOCARCINOMA.

F. "SPLEEN":

SPLEEN (110 GRAMS) WITH MULTIPLE CAPSULAR SURFACE DEPOSITS OF SEROUS CYSTADENOCARCINOMA.

G. "OMENTUM":

OMENTAL TISSUE WITH DEPOSITS OF SEROUS CYSTADENOCARCINOMA.

Verified by:

ADDENDUM 1:

Immunostaining for carcinoembryonic antigen (CEA) is performed on sections from Block A1 ("right ovary") and G1 ("omentum"). The immunostaining is done using DAKO rabbit anti-human CEA which is "the purified immunoglobulin fraction of rabbit antiserum (DAKO product A115). The histological sections of ovary contains abundant adenocarcinoma for evaluation. The tumor cells stain focally for carcinoembryonic antigen. The cells that stain positively are scattered throughout the tumor, and I estimate that the positively staining cells comprise only 1 to 2% of the population. The positively staining cells exhibit mildly intense staining. There are focal areas within the tumor where there is a greater percentage of cells which stain positively (approximately 1/3 of the tumor cells are positive), but this is compensated for by other areas in which none of the tumor cells stain positively. Overall, there is insignificant expression of CEA by the tumor.

The histological sections from the omentum also contain abundant tumor. There is no significant staining of the tumor cells for carcinoembryonic antigen.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 98ea117e-073d-463b-bf86-96538d3a9e92 (TCGA-29-1688.CB2BD608-B9D4-497E-9058-2269DC86B5B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).